Somatic mutation profile of tumor specimen MP2PRT-PASYCR-TMP1-A (aliquot MP2PRT-PASYCR-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASYCR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 16.8 years (6,133 days).
Specimen MP2PRT-PASYCR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97857f27-b54e-4599-aa70-f52adbcc83e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYCR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYCR-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03d96417-2dc0-40d5-b946-298115320cfe

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 2, 3'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3469C>T p.R1157W | Missense Mutation (SNP) | VAF 178/536 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM122495, COSV60789213; called by muse, mutect2, varscan2
- ADAMTS15 | c.1257C>T p.H419= | Splice Region (SNP) | VAF 117/270 reads (43%) | catalogued as rs759292288, COSV100143469; called by muse, mutect2, varscan2
- DST | c.21631C>T p.R7211* (on ENST00000361203 / NM_001374722.1; = p.R4908* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 89/315 reads (28%) | catalogued as COSV55013978; called by muse, mutect2, varscan2
- DST | c.17159G>A p.R5720Q (on ENST00000361203 / NM_001374722.1; = p.R3417Q on NM_015548.5) | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs376690317; called by muse, mutect2, varscan2
- ITPRID1 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 154/448 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138066602; called by muse, mutect2
- PSG7 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 261/633 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs181621391, COSV68444247, COSV68446558; called by muse, mutect2, varscan2
- RELN | c.9904G>A p.A3302T | Missense Mutation (SNP) | VAF 145/325 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs776769644, COSV59040921; called by muse, mutect2, varscan2
- SLC38A11 | c.183G>C p.L61F | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100366868; called by muse, mutect2, varscan2
- SZT2 | c.7061G>A p.R2354Q (on ENST00000634258 / NM_001365999.1; = p.R2297Q on NM_015284.4) | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs371294068; called by muse, mutect2, varscan2
- AGAP4 | c.425T>A p.I142K | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- CCDC168 | c.8707G>C p.D2903H | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- INO80 | c.4223C>G p.S1408* | Nonsense Mutation (SNP) | VAF 99/266 reads (37%) | called by muse, mutect2, varscan2
- LAMA5 | c.3488C>A p.A1163D | Missense Mutation (SNP) | VAF 161/372 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- NGRN | c.64_71del p.F22Pfs*72 | Frame Shift Del (DEL) | VAF 144/571 reads (25%) | called by mutect2, pindel*, varscan2
- SLC2A6 | c.53A>G p.E18G | Missense Mutation (SNP) | VAF 232/589 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SLC9A1 | c.2188G>C p.V730L | Missense Mutation (SNP) | VAF 156/386 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TBKBP1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 154/383 reads (40%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ZFP92 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 233/357 reads (65%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF836 | c.1720A>G p.R574G | Missense Mutation (SNP) | VAF 135/344 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANKS6 | c.1152C>T p.A384= | Silent (SNP) | VAF 30/380 reads (8%) | catalogued as rs752634648; called by muse, mutect2
- BDKRB2 | c.324C>T p.C108= | Silent (SNP) | VAF 188/465 reads (40%) | catalogued as rs201395940; called by muse, mutect2, varscan2
- POU4F3 | c.906G>A p.E302= | Silent (SNP) | VAF 225/487 reads (46%) | catalogued as rs757342833; called by muse, mutect2, varscan2
- PREX2 | c.4656C>T p.H1552= | Silent (SNP) | VAF 174/446 reads (39%) | catalogued as rs372243032; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1398C>T p.D466= (on ENST00000352766; = p.D387= on NM_181334.5) | Silent (SNP) | VAF 102/320 reads (32%) | catalogued as rs142806387; called by muse, varscan2
- IGKV4-1 | chr2:88886153 ins C | 3'Flank (INS) | VAF 58/126 reads (46%) | called by mutect2, pindel, varscan2
